Surgical pathology report (de-identified scan), TCGA case TCGA-14-0865, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0865-01B (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

TCGA-14-0865

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient:
Accession Number:
Patient Number:
Date Collected:
Financial Number:
Date Received:
Room/Bed: PT:
Admitting Physician:
Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, CRANIOTOMY, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME WITH A PREDOMINANTLY SMALL CELL PATTERN (WHO GRADE IV).
2. BRAIN, RIGHT, CRANIOTOMY, BIOPSY:
- GLIOBLASTOMA MULTIFORME WITH A PREDOMINANTLY SMALL CELL PATTERN (WHO GRADE IV).

(Electronic Signature)

SPECIMEN:

1. Right side brain tissue lesion,
2. Right side brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Right craniotomy brain tumor.

PREOPERATIVE DIAGNOSIS: Right brain tumor.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
AP Report

* Final Report *

TCGA-14-0865

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation labeled with the patient's name, hospital number and as "right side brain tissue lesion". The specimen consists of multiple tan-brown, rubbery, friable pieces of soft tissue measuring 1.5 x 1.0 x 0.5 cm in aggregate. One portion is submitted for intraoperative consultation and frozen section diagnosis and the remainder of the cryoblock is submitted in cassette "FS1A". The remainder of the tissue is submitted in cassette "1B".

Specimen #2 is received in formalin and is labeled with the patient's name, hospital number and as "right side brain lesion". The specimen consists of multiple tan, hemorrhagic, gelatinous, friable pieces of soft tissue measuring 1.9 x 1.2 x 1.0 cm in aggregate. The specimen is entirely submitted in cassettes "2A" and "2B".

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT SIDE BRAIN TISSUE LESION (FROZEN SECTION AND TOUCH PREP):
GLIOBLASTOMA MULTIFORME.

Pathologist:

TISSUE COMMITTEE CODE:

1

Fellow:

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.9

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 0ad4fe0d-21d7-497b-a476-7428180383d3 (TCGA-14-0865.318D5B9D-FB2D-4402-8E65-B965DEBF5D70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).